Gene-level copy-number profile of tumor specimen TCGA-86-A4D0-01A from TCGA case TCGA-86-A4D0, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 48.2 years (17,607 days).
Specimen TCGA-86-A4D0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.f44c4488-7cad-480b-ae64-95d4eb3adc72.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-86-A4D0-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4f3e2291-451d-4997-8c6b-bed67d914d78

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 9,990; copy number 2: 36,100; copy number 3: 10,633; copy number 4: 596; copy number 5: 195; copy number 6: 382; copy number 7: 1,065; copy number 8: 454; copy number 9: 252; copy number 10: 67; copy number 12: 40; copy number 14: 43.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-86-A4D0-01A-11D-A24C-01): tumor purity 0.79, ploidy 2.09, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:71,738,173–71,837,012, 2 genes: AL359821.1, NEGR1-IT1.
- chr13:91,485,793–91,486,870, 1 gene: AL356118.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,498 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:12,574,830–21,196,860, 118 genes, copy number 5–7 (broad region; genes not listed).
- chr5:31,532,287–42,802,439, 192 genes, copy number 6 (broad region; genes not listed).
- chr5:42,806,394–42,806,997, 1 gene, copy number 6: AC008945.1.
- chr8:38,062,881–39,730,065, 45 genes, copy number 7: AP006545.1, AP006545.3, AP006545.2, ASH2L, RNU6-988P, AC084024.1, STAR, AC084024.3, LSM1, RNU6-323P, BAG4, AC084024.2, AC084024.4, DDHD2, PLPP5, NSD3, AC087362.2, AC087362.1, AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22, C8orf86, AC069120.1, RNF5P1, AC016813.1, TACC1, Y_RNA, AC067817.1, AC067817.2, PLEKHA2, AC108863.1, HTRA4, TM2D2, ADAM9, SNORD38D, ADAM32, RPL3P10, AC105185.1, ADAM5, ADAM3A, AC123767.1, ADAM18.
- chr8:41,261,962–41,440,419, 7 genes, copy number 6: SFRP1, MIR548AO, RPS29P2, AC104393.1, RNU6-895P, SNORD65B, AC016868.1.
- chr8:41,653,220–41,896,762, 1 gene, copy number 7 (within-gene range 3–7): ANK1.
- chr8:41,803,349–145,066,685, 1,594 genes, copy number 7–9 (broad region; genes not listed).
- chr14:22,701,476–23,578,790, 60 genes, copy number 5: AL160314.2, OR6E1P, AL160314.3, AL135998.1, OXA1L, SLC7A7, MRPL52, MMP14, Y_RNA, Y_RNA, LRP10, REM2, RBM23, PRMT5-AS1, PRMT5, AL132780.1, HAUS4, AL132780.3, MIR4707, AJUBA, AL132780.2, C14orf93, AL132780.5, PSMB5, AL132780.4, PSMB11, CDH24, ACIN1, C14orf119, LMLN2, CEBPE, SLC7A8, RNU6-1138P, RNF212B, AL049829.1, RNU6-1046P, HOMEZ, H3P37, PPP1R3E, BCL2L2, BCL2L2-PABPN1, PABPN1, SLC22A17, EFS, AL049829.2, IL25, CMTM5, MYH6, MIR208A, MYH7, AL132855.1, MIR208B, NGDN, ZFHX2-AS1, ZFHX2, AL135999.2, THTPA, AP1G2, AL135999.1, JPH4.
- chr14:28,592,223–28,613,623, 1 gene, copy number 5 (within-gene range 4–5): LINC02300.
- chr14:28,673,241–42,989,483, 218 genes, copy number 5–12 (broad region; genes not listed).
- chr14:43,990,539–44,866,247, 10 genes, copy number 5–6: LINC02307, EIF4BP1, AL109766.1, YWHAZP1, AL161752.1, LINC02277, FSCB, AL356022.1, LINC02302, DOCK11P1.
- chr22:20,652,730–22,381,347, 135 genes, copy number 6–7 (broad region; genes not listed).
- chr22:38,032,165–41,092,566, 116 genes, copy number 6–14 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 7,870. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
